Somatic mutation profile of tumor specimen MP2PRT-PAUEFU-TMP1-A (aliquot MP2PRT-PAUEFU-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUEFU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,571 days).
Specimen MP2PRT-PAUEFU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a873af6-546a-45d1-9e6b-9d37a8d43384.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUEFU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUEFU-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5e606cf-77e8-4925-83c8-9269a309f129

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 10, Silent 7, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSNK1A1L | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 132/298 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs775483694; called by muse, mutect2, varscan2
- JAK2 | c.2044A>T p.I682F | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV67612617; called by muse, varscan2
- KLHL32 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 24/545 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs150244885; called by muse, mutect2
- KMT2D | c.7228C>T p.R2410* | Nonsense Mutation (SNP) | VAF 260/544 reads (48%) | catalogued as CM114905, COSV56416426; called by muse, mutect2, varscan2
- PAPPA2 | c.3284C>T p.A1095V | Missense Mutation (SNP) | VAF 130/286 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as COSV62800705; called by muse, mutect2, varscan2
- PCDH19 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 267/600 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753757730, CM118954; called by muse, mutect2, varscan2
- PTPRT | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 193/389 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs751630191, COSV61957890; called by muse, mutect2, varscan2
- EPG5 | c.5672T>C p.M1891T | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM83E | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 248/502 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV2-30 | chr2:89244772 CACTGTGGGAGGCCA>GGAG | Missense Mutation (DEL) | VAF 17/55 reads (31%) | called by pindel, varscan2*
- JPH4 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 63/704 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.284); called by muse, mutect2
- ADGRB2 | c.3495G>A p.A1165= | Silent (SNP) | VAF 205/437 reads (47%) | catalogued as rs746831638, COSV57072309; called by muse, mutect2, varscan2
- KIT | c.2604C>T p.S868= | Silent (SNP) | VAF 14/350 reads (4%) | called by muse, mutect2
- MAB21L4 | c.1059G>A p.L353= (on ENST00000388934 / NM_001085437.3; = p.L185= on NM_024861.4) | Silent (SNP) | VAF 307/694 reads (44%) | called by muse, mutect2, varscan2
- NCAM1 | c.2541C>T p.D847= (on ENST00000316851 / NM_181351.5; = p.D837= on NM_000615.7) | Silent (SNP) | VAF 150/327 reads (46%) | catalogued as rs369914244; called by muse, mutect2, varscan2
- NDN | c.636C>T p.N212= | Silent (SNP) | VAF 58/482 reads (12%) | catalogued as rs901682735, COSV59360220; called by muse, mutect2, varscan2
- NXN | c.855C>T p.G285= | Silent (SNP) | VAF 207/490 reads (42%) | catalogued as rs770149423, COSV61095840; called by muse, mutect2, varscan2
- OR51G1 | c.816C>T p.R272= | Silent (SNP) | VAF 189/414 reads (46%) | catalogued as rs372747926, COSV58969349; called by muse, mutect2, varscan2
